Gene-level copy-number profile of tumor specimen TCGA-04-1536-01A from TCGA case TCGA-04-1536, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 60.1 years (21,939 days).
Specimen TCGA-04-1536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c65769ca-85bb-4730-a7d7-4fb0776baed8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1536-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a394bec3-498c-405e-9a70-e1b8f6c00979

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,531; copy number 2: 18,418; copy number 3: 17,397; copy number 4: 12,463; copy number 5: 2,142; copy number 6: 2,742; copy number 7: 2,057; copy number 8: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1536-01): tumor purity 0.76, ploidy 2.95, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,296,162–48,303,661, 1 gene: RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,061 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–119,896,515, 36 genes, copy number 7: TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30.
- chr1:147,019,656–147,842,359, 28 genes, copy number 6 (within-gene range 3–6): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1.
- chr1:149,782,689–149,812,373, 1 gene, copy number 6 (within-gene range 3–6): H2BC18.
- chr1:149,813,225–205,285,632, 1,414 genes, copy number 5–8 (broad region; genes not listed).
- chr2:158,127,957–159,798,255, 32 genes, copy number 5: UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302.
- chr2:159,797,288–159,798,043, 1 gene, copy number 5: AC009961.3.
- chr2:159,812,234–159,814,009, 1 gene, copy number 5: AC009961.2.
- chr3:80,163,327–84,051,419, 24 genes, copy number 5: OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:138,347,648–143,060,725, 100 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:49,714,325–49,820,503, 1 gene, copy number 6 (within-gene range 3–6): AL121974.1.
- chr6:49,727,376–50,181,007, 10 genes, copy number 6 (within-gene range 3–6): CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr7:52,891,837–54,938,184, 29 genes, copy number 5: SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1.
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 6–7 (broad region; genes not listed).
- chr8:112,222,928–113,436,939, 1 gene, copy number 6 (within-gene range 3–6): CSMD3.
- chr8:112,643,493–139,508,971, 308 genes, copy number 5–7 (broad region; genes not listed).
- chr9:60,914,407–93,679,587, 545 genes, copy number 5 (broad region; genes not listed).
- chr11:65,597,756–67,683,058, 138 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5–7 (broad region; genes not listed).
- chr20:46,859,333–64,313,132, 420 genes, copy number 5–7 (broad region; genes not listed).
- chr21:41,885,112–46,665,124, 187 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
